Somatic mutation profile of tumor specimen TCGA-AR-A24V-01A (aliquot TCGA-AR-A24V-01A-21D-A167-09) from TCGA case TCGA-AR-A24V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 52.1 years (19,027 days).
Specimen TCGA-AR-A24V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19da31fe-ced3-459e-a265-68cb91aaa25e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24V-10A (Blood Derived Normal), aliquot TCGA-AR-A24V-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa8ac57c-1095-49e0-883c-8a8f1adf6f02

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPH | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739446; called by muse, mutect2, varscan2
- BCO1 | c.1142C>G p.T381R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs888549373, COSV50728986; called by muse, mutect2, varscan2
- C2CD6 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs576434498, COSV53793572; called by muse, mutect2, varscan2
- CEP290 | c.2338C>G p.Q780E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100470237; called by muse, mutect2, varscan2
- FHOD3 | c.2327C>G p.A776G (on ENST00000359247 / NM_001281739.3; = p.A793G on NM_025135.5) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV99943628; called by muse, mutect2
- FRYL | c.1568A>T p.D523V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51944710; called by muse, mutect2, varscan2
- HEXB | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV54667476; called by muse, mutect2, varscan2
- OR4A5 | c.170T>A p.M57K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV60522201; called by muse, mutect2, varscan2
- PKDREJ | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1300049862, COSV53548518; called by muse, mutect2, varscan2
- RBM14 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1052652681, COSV59557880; called by muse, mutect2, varscan2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by muse, mutect2
- SLCO1C1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56868337; called by muse, mutect2, varscan2
- TFB2M | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs988862969, COSV63624881; called by muse, mutect2, varscan2
- TRPV3 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753934400, COSV56790499; called by muse, mutect2, varscan2
- ZBTB4 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1161112700, COSV60978503; called by muse, mutect2, varscan2
- ZDHHC9 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64096453; called by muse, mutect2, varscan2
- CACNG8 | c.297C>T p.G99= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs754159629, COSV54414447; called by muse, mutect2, varscan2
- CERS3 | c.486A>G p.L162= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV52567171; called by muse, mutect2, varscan2
- CYP7B1 | c.486A>G p.K162= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV59586298; called by muse, mutect2, varscan2
- NMI | c.9T>C p.A3= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs771346022, COSV54637918; called by muse, mutect2, varscan2
- SCN4A | c.4389C>T p.R1463= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs763124097, COSV71126393; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNTG1 | c.822C>A p.I274= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV52437155, COSV52461772; called by muse, mutect2, varscan2
